Somatic mutation profile of tumor specimen 0DWKH1 from CCDI case PBCPAJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 20.2 years (7,378 days).
Specimen 0DWKH1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e7478eb-57aa-4643-9d5b-e7efd254c322.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWKG0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c010ebda-c2a3-444c-bf5c-0b92f85098ee

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 4, Frame Shift Del 2, Intron 2, 5'UTR 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 185/586 reads (32%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.821T>C p.V274A | Missense Mutation (SNP) | VAF 642/921 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1057520006, COSV52662012, COSV52709979, COSV52761348, COSV53124293; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ASXL3 | c.6246A>T p.E2082D | Missense Mutation (SNP) | VAF 302/1351 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as rs902703242; called by muse, mutect2, varscan2
- HHIPL2 | c.1772G>A p.R591H | Missense Mutation (SNP) | VAF 68/1107 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375638252, COSV58564629; called by muse, mutect2
- KDSR | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 94/966 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); catalogued as rs1038226452; called by muse, mutect2
- KMT2C | c.954G>T p.Q318H | Missense Mutation (SNP) | VAF 77/2224 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV51450036, COSV51497014; called by muse, mutect2
- MFSD8 | c.29A>G p.Q10R | Missense Mutation (SNP) | VAF 134/652 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs532843679; called by muse, mutect2, varscan2
- PRKAB2 | c.122A>G p.D41G | Missense Mutation (SNP) | VAF 106/524 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV54213985; called by muse, mutect2
- UBASH3A | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 75/1084 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs547906042, COSV99369770; called by muse, mutect2
- USP20 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 25/332 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373465499; called by muse, mutect2
- EIF4A2 | c.193_196del p.I65Pfs*8 | Frame Shift Del (DEL) | VAF 296/1072 reads (28%) | called by mutect2, varscan2
- KIAA1614 | c.1256G>C p.R419T | Missense Mutation (SNP) | VAF 280/750 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- KLRB1 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 124/1557 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.796); called by muse, mutect2
- LTK | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 145/440 reads (33%) | called by muse, mutect2, varscan2
- MAGI2 | c.1302G>C p.M434I | Missense Mutation (SNP) | VAF 106/2388 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2
- MAPK15 | c.118G>C p.A40P | Missense Mutation (SNP) | VAF 64/1176 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYO18B | c.2759_2760del p.F920Cfs*44 | Frame Shift Del (DEL) | VAF 183/654 reads (28%) | called by mutect2, varscan2
- TPRX1 | c.866G>C p.S289T | Missense Mutation (SNP) | VAF 78/1016 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.386); called by muse, mutect2
- FCRL2 | c.390C>A p.T130= | Silent (SNP) | VAF 273/846 reads (32%) | catalogued as rs534137363; called by muse, mutect2, varscan2
- ITGA1 | c.1515T>A p.T505= | Silent (SNP) | VAF 333/1313 reads (25%) | called by muse, mutect2, varscan2
- NCAPG2 | c.732C>T p.H244= | Silent (SNP) | VAF 648/1538 reads (42%) | catalogued as rs372309426; called by muse, mutect2, varscan2
- SYCE3 | c.105C>T p.I35= | Silent (SNP) | VAF 59/990 reads (6%) | called by muse, mutect2
- GATM | c.70-53_70-52del | Intron (DEL) | VAF 64/214 reads (30%) | called by mutect2, varscan2
- GOLGA1 | c.*51A>C | 3'UTR (SNP) | VAF 88/215 reads (41%) | called by muse, mutect2, varscan2
- R3HDM1 | c.-13del | 5'UTR (DEL) | VAF 50/398 reads (13%) | called by mutect2, varscan2
- RAP1GAP2 | c.596+26C>T | Intron (SNP) | VAF 20/434 reads (5%) | called by muse, mutect2
